Somatic mutation profile of tumor specimen 0E1CWZ from CCDI case PBCWIE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E1CWZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3be6d0c9-27ce-4c57-98c6-622f2a9cbc8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1CXB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81b07740-4d50-425c-a459-347cecae931c

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BNIP3L | c.330G>A p.M110I | Missense Mutation (SNP) | VAF 117/285 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- GLUD1 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 143/432 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- KANK2 | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- LRRC8D | c.2446C>G p.Q816E | Missense Mutation (SNP) | VAF 19/518 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- OLFM1 | c.-15C>T | 5'UTR (SNP) | VAF 22/53 reads (42%) | called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 18/128 reads (14%) | called by muse, varscan2
